Somatic mutation profile of tumor specimen MP2PRT-PAUCYW-TBP1-A (aliquot MP2PRT-PAUCYW-TBP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PAUCYW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.9 years (2,142 days).
Specimen MP2PRT-PAUCYW-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b2b958f-343e-4bc9-a6f2-531c0635fe9f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUCYW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUCYW-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03373729-090d-4437-9766-d3a0c6d91307

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C1QC | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 255/736 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101009561; called by muse, mutect2, varscan2
- KCNK1 | c.449C>T p.T150M | Missense Mutation (SNP) | VAF 197/608 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs377600307, COSV100785635, COSV100785812; called by muse, mutect2, varscan2
- PPP1R11 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 214/815 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1398067515, COSV54993812; called by muse, mutect2, varscan2
- UCN2 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 188/610 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs762298735, COSV56476343; called by muse, mutect2, varscan2
- HDAC7 | c.2045_2046insGAA p.F682delinsLN (on ENST00000427332; = p.F721delinsLN on NM_015401.5 and 1 other RefSeq transcript) | In Frame Ins (INS) | VAF 100/362 reads (28%) | called by mutect2, pindel, varscan2
- IGHV1-45 | chr14:106506993 GTGTAT>A | Missense Mutation (DEL) | VAF 54/98 reads (55%) | called by pindel, varscan2*
